Surgical pathology report (de-identified scan), TCGA case TCGA-QQ-A5V2, project TCGA-SARC (Sarcoma), tissue source site Roswell Park, specimen TCGA-QQ-A5V2-01A (Primary Tumor).

[page 1 of 2]
TSS DeID:
Surgery Date:

SPECIMENS:

- A. LEFT PELVIC MASS
- B. GIANT CELL TUMOR LEFT ILIUM

DIAGNOSIS:

- A. SOFT TISSUE, LEFT PELVIC; EXCISIONAL BIOPSY:
- GIANT CELL TUMOR.

- B. BONE AND SOFT TISSUE, LEFT ILIUM, RESECTION:
- GIANT CELL TUMOR (19.6 CM) WITH EXTENSIVE CYSTIC DEGENERATION, HEMORRHAGE AND NECROSIS INVOLVING SOFT TISSUE AND BONE.
- BONE MARGINS ARE NOT INVOLVED. SEE COMMENT.

SPECIMEN(S):

- A. LEFT PELVIC MASS B. GIANT CELL TUMOR LEFT ILIUM

CLINICAL HISTORY:

None given

INTRAOPERATIVE CONSULTATION DIAGNOSIS:

FSA - left pelvic mass: Frozen sections consistent with giant cell tumor. By Dr., called to Drs.

GROSS DESCRIPTION:

A. LEFT PELVIC MASS

Received fresh for intraoperative consultation is a portion of tan-red focally hemorrhagic and necrotic soft tissue measuring 3 x 2 x 1 cm. Touch prep was made for the specimen. Representative sections of the specimen are submitted in three cassettes as follows:

FSA1: portion for frozen section

A2-A3: additional representative sections

B. GIANT CELL TUMOR LEFT ILIUM

Received fresh for tissue procurement are two pieces of tissue with the largest represent a soft tissue mass measuring 19.6 x 12 x 9 cm. The second piece represents a portion of bone with attached tumor measuring overall 11 x 10 x 4.5 cm. It appears that the two pieces were previously attached together. The larger piece shows tumor mass with well circumscribed, encapsulated tumor mass with a defect on one surface corresponding to the area of the second tip. Sectioning through the specimen shows a fleshy tumor with extensive necrotic and hemorrhagic areas and variegated tan-red to yellow cut surface. The smaller piece shows a portion of bone with unremarkable margins. The opposite side of the bone is expanded and admixed with the soft tissue of the mass which shows a matching cut surface the tumor in the larger piece. Representative sections are submitted as follows

B1-B12: random sections of tumor from the larger piece

B13-B14: tumor from the larger piece representing the interface between the 2 pieces

B15-B17: tumor from the smaller piece representing the interface between the 2 pieces

The margins of the bone sections showing the relationship of tumor to the bone are submitted following calcification as follows:

B18-B19: bone surgical margins from piece 2

B20: tumor and bone from piece 2

NOTE: Gross photographs are taken for part B.

Tissue procurement was performed on part B.

Tissue is submitted for cytogenetic study from specimen B.

COMMENT:

Although a spindle cell component is focally present, no definite evidence of sarcomatoid transformation is identified in multiple sections.

Rare detached clusters of tumor are present on section B19, but no contiguous relationship with the bone tissue is seen hence these are most likely contaminants. Due to original specimen fragmentation, the soft tissue margin assessment cannot be ascertained. Clinical surgical correlation is advised.

HI/PA Discrepancy		
Prior Biopsy History		

[page 2 of 2]
TCGA Pathologic Diagnosis Discrepancy Form

V1.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Giant Cell Tumor	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	Giant cell, MFH	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	The surgical case was signed out in _____ and classified as Giant cell Tumor based on the limited information available at the time. When the biospecimen that was submitted to TCGA was QC'ed, the case was classified as Giant cell, MFH based upon the current available clinical information.	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director		Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature Date

Source: NCI Genomic Data Commons file 7c460e01-651e-4098-b346-511524ac0394 (TCGA-QQ-A5V2.D012487F-29E2-4425-AB2B-DD8F0D6122A0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).